Surgical pathology report (de-identified scan), TCGA case TCGA-24-2030, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2030-01A (Primary Tumor).

[page 1 of 4]
DIAGNOSIS-

ICGA-24-2030

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- POORLY DIFFERENTIATED PAPILLARY SEROUS
ADENOCARCINOMA

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

OMENTUM, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- SURFACE ADHESIONS AND MESOTHELIAL HYPERPLASIA

UTERUS, CERVIX, ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, ABDOMINAL HYSTERECTOMY - CYSTIC CHANGE

UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY - LEIOMYOMAS

SPECIMEN(S) SUBMITTED

Part 1: LEFT ADNEXA

Part 2: UTERUS, CERVIX, RSO

Part 3: OMENTUM

[page 2 of 4]
[REDACTED]

Name:

Surg. Path. No.:

HISTORY

The patient is an [REDACTED]. No clinical history is given. Operative procedure: Examination under anesthesia, EL, total abdominal hysterectomy, bilateral salpingo-oophorectomy, and omentectomy. Clinical diagnosis: None given.

GROSS

The specimens are received in three containers of formalin, each labelled with the patient's name. The first container is also labelled "#1, left adnexa." It contains multiple fragments of gray-white, friable, irregular tissue measuring 15 x 15 x 5 cm in aggregate. The cut surfaces are solid and papillary. A membranous surface with a small amount of attached fat is identified, but there is no recognizable ovary or fallopian tube. Labelled A1 to A3 - fragment with membranous surface; A4 to A6 - other fragments with papillary features. [REDACTED]

The second container is labelled "#2, uterus, cervix, RO." It contains a uterus with the attached right adnexa weighing 61 gm and measuring 8 x 4 x 4 cm. The ectocervix measures 1 cm and the external cervical os measures 0.5 cm in diameter. They are grossly unremarkable. The endocervical canal measures 2.5 cm in length. The uterine cavity is 7 cm in length. The uterine cavity is dilated and cystic, measuring 3.5 cm in diameter, and is led with bloody fluid. The endometrium is 0.2 cm in thickness. The myometrium is 0.6 cm in thickness. The endometrium is generally smooth, but shows irregular multicystic flat areas in the fundus in an area measuring 2 cm in diameter. The uterine wall shows multiple intramural leiomyomas measuring between 0.6 and 2 cm in greatest dimensions. The right fallopian tube measures 6 cm in length and 0.4 cm in diameter. Cross sections are unremarkable. The serosa contains multiple hydatids of Morgagni measuring 0.5 cm in diameter. The right ovary measures 2 x 1 x 0.5 cm. The cut surfaces of the ovary are unremarkable. The left adnexa is not identified on this specimen, but there are multiple gray-white, friable papillary structures in the place of the adnexa similar to the fragments described in the first container. Labelled C1 - anterior cervix; C2 - posterior cervix; EM1 - anterior uterine

[page 3 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Surg. Path. No.: [REDACTED]

GROSS (continued)

wall with fundic irregularities in the endometrium; EM2 - posterior uterine wall with fundic irregularities in the endometrium; RT - right fallopian tube; RO - right ovary; M1 and M2 - largest leiomyoma; LA - papillary structures in place of left adnexa. [REDACTED]

The third container is labelled "#3, omentum." It contains two fragments of fibrofatty tissue measuring 12 x 6 x 4 cm and 8 x 6 x 5 cm. The larger fragment contains irregular, friable, gray-white areas measuring 2.5 and 4.5 cm in greatest dimension. Other areas are fibrofatty. The smaller fragment largely consists of a cystic structure surrounded by fibrofatty tissue. The cyst has a smooth surface, irregular lining and contains bloody fluid. There are also multiple fragments of gray-white, friable tissue floating within the cyst. The cyst wall measures 0.2 cm on average. There is also an adjacent gray-white, friable, partially cystic and necrotic area measuring 3 x 3 x 2 cm. Labelled B1 - cyst wall; B2 - floating fragments in the cyst; B3 - adjacent solid and necrotic area; B4 and B5 - solid area in larger fragment. [REDACTED]

COMMENT

The specimen submitted as "left adnexa" consists of a poorly differentiated papillary serous adenocarcinoma. Most of the submitted tissue is composed of tumor, but there is a small amount of residual ovarian parenchyma identified within the tumor mass. The left fallopian tube is also identified and is involved by tumor. Focally, the tumor extends through the tubal muscularis and is present in the lamina propria. The omentum is also extensively replaced by papillary serous adenocarcinoma. There are no significant histopathologic abnormalities in the right ovary or fallopian tube. The cervix is unremarkable. The endometrium shows extensive cystic change. Leiomyomas are identified in the myometrium. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

- 1a. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma [REDACTED]

[page 4 of 4]
[REDACTED]

COMMENT (continued)

3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Left ovary only [REDACTED]
4. The FIGO GRADE of the tumor is:
II (Tumor composed of 5-50% solid cellular nests) [REDACTED]
III (Tumor composed of greater than 50% solid cellular
nests) [REDACTED]
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated) [REDACTED]
7. Tumor DOES invade the mesovarium. [REDACTED]
8. Tumor DOES invade the adjacent fallopian tube. [REDACTED]
12. Metastatic involvement of the omentum is PRESENT. [REDACTED]
14. Metastatic involvement of the uterine serosa is ABSENT.
15. [REDACTED] involvement of the endometrium is ABSENT.
16. [REDACTED] Regional lymph node metastases CANNOT BE EVALUATED |
17. The total number of regional lymph nodes examined is 0. [REDACTED]
20. The FINAL AJCC/FIGO STAGE: Requires clinical correlation.

{End of Report}

[REDACTED]

Source: NCI Genomic Data Commons file 5e3317d6-b492-488a-992c-2675fc22319d (TCGA-24-2030.BB1B63AB-1E13-4401-AB6A-0325DA96B17F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).